FM case AD922 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/4d5c4e78-f48f-4add-a6ce-ceecef26d86f

Male, 48.3 years: Adenocarcinoma, NOS (ICD-O-3 8140/3). Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
